Somatic mutation profile of tumor specimen TCGA-CR-7399-01A (aliquot TCGA-CR-7399-01A-11D-2012-08) from TCGA case TCGA-CR-7399, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 60.7 years (22,182 days).
Specimen TCGA-CR-7399-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d96e1ca-4c55-4af0-a6ef-c60aa3488eeb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7399-10A (Blood Derived Normal), aliquot TCGA-CR-7399-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08ae746a-1060-4e29-8554-2d5c866fea79

The open-access MAF lists 306 somatic variants for this specimen: 239 protein-altering or splice-affecting, 58 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 196, Silent 58, Nonsense Mutation 20, Frame Shift Del 12, Splice Site 9, Intron 6, Frame Shift Ins 1, Splice Region 1, 5'UTR 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PLCE1 | c.5560C>T p.Q1854* | Nonsense Mutation (SNP) | VAF 18/103 reads (17%) | catalogued as rs121912604, CM066176, COSV99596908; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.3458T>A p.L1153Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100217675; called by muse, mutect2, varscan2
- ACVRL1 | c.1160C>A p.T387K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.689); catalogued as COSV101188111; called by muse, mutect2, varscan2
- ADAM7 | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV99444931; called by muse, mutect2, varscan2
- ADAMTS2 | c.303C>A p.N101K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0.03); catalogued as rs373406403; called by muse, mutect2, varscan2
- ADCY8 | c.1688A>G p.Y563C | Missense Mutation (SNP) | VAF 41/274 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99654070; called by muse, mutect2, varscan2
- ADRA1A | c.896C>A p.P299H | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV52362905, COSV99370686; called by muse, mutect2, varscan2
- AHNAK2 | c.13540C>G p.Q4514E | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.821); catalogued as COSV100318807; called by muse, varscan2
- AKAP9 | c.6104A>G p.K2035R (on ENST00000359028; = p.K2003R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV100662993; called by muse, mutect2, varscan2
- ALPK2 | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as rs200278400; called by muse, mutect2, varscan2
- ANK2 | c.10816C>A p.P3606T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100003895, COSV52194991; called by muse, mutect2, varscan2
- ANKRD17 | c.6719C>T p.P2240L | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV100429890; called by muse, mutect2, varscan2
- ARHGAP26 | c.996G>T p.K332N | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV99191361; called by muse, mutect2, varscan2
- ARHGEF25 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99678266; called by muse, mutect2, varscan2
- ARMCX2 | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.386); catalogued as COSV100168265; called by muse, mutect2, varscan2
- ARMH3 | c.813C>G p.F271L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV100899024; called by muse, mutect2, varscan2
- ARPC4 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.752); catalogued as COSV99809624; called by muse, mutect2, varscan2
- ARRDC5 | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV101108253; called by muse, mutect2, varscan2
- ATP8A1 | c.3159G>A p.M1053I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV100047202; called by muse, mutect2, varscan2
- AWAT2 | c.782A>G p.Y261C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs772011125, COSV99339759; called by muse, mutect2, varscan2
- AXL | c.1703C>T p.T568M (on ENST00000301178 / NM_021913.5; = p.T559M on NM_001699.6) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749923407, COSV56575042; called by mutect2, varscan2
- AZGP1 | c.461G>A p.W154* | Nonsense Mutation (SNP) | VAF 51/332 reads (15%) | catalogued as rs145427176, COSV52797108; called by muse, mutect2, varscan2
- BMT2 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99774831; called by muse, mutect2, varscan2
- BRWD3 | c.747G>C p.W249C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100956461; called by muse, mutect2, varscan2
- BUB1 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV100241616; called by muse, mutect2, varscan2
- CACNA1D | c.3802G>T p.A1268S (on ENST00000350061 / NM_001128840.3; = p.A1288S on NM_000720.4) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV55443096, COSV99859817; called by muse, mutect2, varscan2
- CBLN2 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV54050178, COSV99504092; called by muse, mutect2, varscan2
- CCSER2 | c.1501C>T p.L501F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99826410; called by muse, mutect2, varscan2
- CDC6 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99266671; called by muse, mutect2, varscan2
- CDH10 | c.985A>C p.I329L | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as COSV100052936; called by muse, mutect2, varscan2
- CDKL5 | c.2343G>T p.R781S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as CD052095, COSV101184444; called by muse, mutect2, varscan2
- CEP170 | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 26/152 reads (17%) | catalogued as COSV100317751; called by muse, mutect2, varscan2
- CKB | c.841C>G p.L281V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100818954; called by muse, mutect2, varscan2
- CNKSR1 | c.1052C>T p.P351L (on ENST00000374253 / NM_001297647.2; = p.P344L on NM_006314.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100836786; called by muse, mutect2, varscan2
- CNTN6 | c.358+1G>T p.X120_splice | Splice Site (SNP) | VAF 31/138 reads (22%) | catalogued as COSV100611756, COSV63189965; called by muse, mutect2, varscan2
- CNTROB | c.2245C>T p.Q749* | Nonsense Mutation (SNP) | VAF 20/139 reads (14%) | catalogued as COSV100972756; called by muse, mutect2, varscan2
- COL17A1 | c.3872G>A p.G1291D | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs781143436, COSV100212081; called by mutect2, varscan2
- COL4A4 | c.2284C>A p.P762T | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100307605; called by muse, mutect2, varscan2
- COL9A2 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749078666, COSV101028743; called by mutect2, varscan2
- CRHR2 | c.267G>A p.W89* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100530146; called by muse, mutect2, varscan2
- CSMD3 | c.10759G>T p.G3587* (on ENST00000297405 / NM_001363185.1; = p.G3418* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | catalogued as rs1434625159, COSV99846174; called by muse, mutect2, varscan2
- CSMD3 | c.494del p.G165Dfs*41 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | catalogued as COSV52120004; called by mutect2, pindel
- CTNNA2 | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV100785871; called by muse, mutect2, varscan2
- DCX | c.705+1G>T p.X235_splice | Splice Site (SNP) | VAF 32/161 reads (20%) | catalogued as CS982159, COSV100576724; called by muse, mutect2, varscan2
- DENND3 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1164686761, COSV52802220; called by muse, mutect2, varscan2
- DIS3L2 | c.1836del p.Q614Kfs*31 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | catalogued as rs1559216207; called by pindel, varscan2
- DLL3 | c.699G>T p.Q233H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV99219441; called by muse, mutect2, varscan2
- DMD | c.5448G>A p.M1816I | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.205); catalogued as COSV100822375; called by muse, mutect2, varscan2
- DNAH5 | c.12284G>A p.G4095E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV99453586; called by muse, mutect2, varscan2
- DNASE1L1 | c.588C>A p.D196E | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99186286; called by muse, mutect2, varscan2
- DNMT3A | c.1121A>T p.Q374L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV99264234; called by muse, mutect2, varscan2
- DPYS | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs368802826; called by muse, mutect2, varscan2
- DST | c.18464A>T p.E6155V (on ENST00000361203 / NM_001374722.1; = p.E3852V on NM_015548.5) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99759499; called by mutect2, varscan2
- DZIP1L | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.096); catalogued as rs376723739, COSV59522815; called by muse, mutect2, varscan2
- DZIP3 | c.2052G>T p.K684N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100848042; called by muse, mutect2, varscan2
- ENPP4 | c.370C>G p.Q124E | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV100320444, COSV58088590; called by muse, mutect2, varscan2
- ENPP6 | c.1051C>A p.R351S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs767125002, COSV99699111; called by muse, mutect2, varscan2
- EPHB1 | c.617T>C p.F206S | Missense Mutation (SNP) | VAF 42/299 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101214253; called by muse, mutect2, varscan2
- F10 | c.1370C>A p.A457D | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV100979324; called by muse, mutect2, varscan2
- F3 | c.751+1G>A p.X251_splice | Splice Site (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100474419; called by muse, varscan2
- FADS6 | c.672G>T p.W224C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV100044380, COSV59604146; called by muse, mutect2, varscan2
- FAM135B | c.78G>A p.G26= | Splice Region (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99358041; called by muse, mutect2, varscan2
- FANCB | c.901G>C p.V301L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV100146675; called by muse, mutect2, varscan2
- FBXO10 | c.2305A>T p.T769S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as COSV99447217; called by muse, mutect2, varscan2
- FEN1 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV57250749, COSV99952957; called by muse, mutect2, varscan2
- FGF12 | c.265C>A p.P89T (on ENST00000454309 / NM_021032.5; = p.P27T on NM_004113.6) | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV53160381; called by muse, mutect2, varscan2
- FLII | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as COSV100493804; called by muse, mutect2, varscan2
- FOXJ2 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.199); catalogued as COSV99368911; called by muse, mutect2, varscan2
- FTMT | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV100360438; called by muse, mutect2, varscan2
- GABRA2 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100734718; called by muse, mutect2, varscan2
- GATA3 | c.290T>A p.L97Q | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV100651216; called by muse, mutect2, varscan2
- GBA3 | c.769C>A p.P257T | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774684451, COSV101545564; called by muse, mutect2, varscan2
- GDF6 | c.1357G>A p.G453S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1178158158, COSV99748500; called by muse, mutect2, varscan2
- GDI2 | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV101200805; called by muse, mutect2, varscan2
- GEM | c.171C>A p.S57R | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV99891605; called by muse, mutect2, varscan2
- GJC3 | c.404G>T p.W135L | Missense Mutation (SNP) | VAF 37/266 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as COSV100458511; called by muse, mutect2, varscan2
- GPC3 | c.297G>T p.E99D | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.102); catalogued as COSV100893506; called by muse, mutect2, varscan2
- GPR75 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM016270, COSV100766388; called by muse, mutect2
- GPRIN3 | c.1818C>A p.S606R | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV100310982; called by muse, mutect2, varscan2
- GPT2 | c.1130C>A p.P377H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100413052; called by muse, mutect2, varscan2
- GRIN2B | c.4009G>C p.A1337P | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs201335987, COSV101663174, COSV74205415, COSV74206068; called by muse, mutect2, varscan2
- GRM1 | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV99268659; called by muse, mutect2, varscan2
- GSTCD | c.1352G>A p.G451D (on ENST00000360505 / NM_001031720.3; = p.G364D on NM_024751.3) | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100853873; called by muse, mutect2, varscan2
- HACD2 | c.373G>T p.V125F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.477); catalogued as COSV101046138; called by muse, mutect2, varscan2
- HEATR1 | c.4435+2T>A p.X1479_splice | Splice Site (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100857787; called by muse, mutect2, varscan2
- HGF | c.446G>A p.C149Y | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753731630, COSV99738319; called by muse, mutect2, varscan2
- HOXB6 | c.602G>A p.W201* | Nonsense Mutation (SNP) | VAF 46/290 reads (16%) | catalogued as COSV99494722; called by muse, mutect2, varscan2
- IFNA4 | c.167G>T p.R56I | Missense Mutation (SNP) | VAF 105/254 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV101427082; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1641G>C p.L547F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.809); catalogued as COSV100150049; called by muse, mutect2, varscan2
- IMPG1 | c.704G>T p.R235M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100886628; called by muse, mutect2, varscan2
- INHBB | c.1194C>A p.N398K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99736163; called by muse, varscan2
- IPO8 | c.2395C>T p.H799Y | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as rs916701937, COSV99805624; called by muse, mutect2, varscan2
- ISOC1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1334569408, COSV99434692; called by muse, mutect2, varscan2
- ITGBL1 | c.1149del p.C384Vfs*23 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | catalogued as COSV66012386; called by mutect2, pindel, varscan2
- KCNB2 | c.149G>T p.W50L | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV101578990; called by muse, mutect2, varscan2
- KCNH4 | c.2365del p.Q789Rfs*39 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as COSV52921691; called by mutect2, pindel
- KCNK16 | c.30G>T p.W10C | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100949311; called by muse, mutect2, varscan2
- KCNQ3 | c.2525C>T p.T842M | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs202163980, COSV101195746; called by mutect2, varscan2
- KIF26B | c.3611G>A p.S1204N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100833314; called by muse, mutect2, varscan2
- KNDC1 | c.2603G>T p.R868L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100466080; called by mutect2, varscan2
- KRTAP15-1 | c.188C>A p.T63K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.123); catalogued as rs767222787, COSV100481653; called by muse, mutect2, varscan2
- KRTAP5-7 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 349/547 reads (64%) | PolyPhen probably damaging (0.97); catalogued as COSV101273239; called by muse, mutect2, varscan2
- KRTAP5-7 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 352/551 reads (64%) | PolyPhen probably damaging (0.988); catalogued as COSV101273240, COSV68325333; called by muse, mutect2, varscan2
- LETM2 | c.979G>A p.D327N (on ENST00000379957 / NM_001286819.2; = p.D232N on NM_144652.3) | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99907602; called by muse, mutect2, varscan2
- LPA | c.3585G>A p.M1195I | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.782); catalogued as COSV100307948; called by muse, mutect2, varscan2
- LRP1B | c.7354G>A p.G2452R | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101260222; called by muse, mutect2, varscan2
- LRRC36 | c.1235T>C p.V412A | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV99339062; called by muse, mutect2, varscan2
- LRRC7 | c.964G>A p.D322N (on ENST00000651989 / NM_001370785.2; = p.D289N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV50496995, COSV50601277; called by muse, mutect2, varscan2
- LRRN1 | c.1973G>A p.R658K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.297); catalogued as rs75344244, COSV100076576; called by muse, mutect2, varscan2
- LRRN3 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.71); catalogued as rs1010466126, COSV100073081, COSV100073732; called by muse, mutect2, varscan2
- LRRTM1 | c.1178C>A p.T393K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs917603256, COSV99703058; called by muse, mutect2, varscan2
- LUZP4 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100904880; called by muse, mutect2, varscan2
- MARCHF6 | c.2065A>G p.I689V | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1431071773, COSV56888437; called by muse, mutect2, varscan2
- MARS1 | c.2263A>G p.M755V | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1443510181, COSV100007627; called by muse, mutect2, varscan2
- MASP1 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99397567; called by muse, mutect2
- MBL2 | c.329C>G p.S110* | Nonsense Mutation (SNP) | VAF 21/140 reads (15%) | catalogued as COSV100906397; called by muse, mutect2, varscan2
- MCF2 | c.687G>T p.Q229H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV100645081; called by muse, mutect2, varscan2
- METRNL | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs146370282; called by muse, mutect2, varscan2
- MIA2 | c.1595G>T p.R532I | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99698152; called by muse, mutect2, varscan2
- MIGA1 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV100889808; called by muse, mutect2, varscan2
- MKRN3 | c.683C>A p.S228* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100091567; called by muse, mutect2, varscan2
- MMP8 | c.88A>G p.T30A | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV99368853; called by muse, mutect2, varscan2
- MTMR8 | c.946A>C p.I316L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs1321711366, COSV100878561; called by muse, mutect2, varscan2
- MUC16 | c.32446G>A p.G10816S | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.563); catalogued as COSV101201371; called by muse, mutect2, varscan2
- MUC16 | c.6046C>T p.H2016Y | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as COSV67475009, COSV67488606; called by muse, mutect2, varscan2
- MYB | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100214953, COSV100215121; called by muse, mutect2, varscan2
- MYBPC1 | c.1000del p.E334Sfs*4 (on ENST00000550270 / NM_206820.2; = p.E359Sfs*4 on NM_002465.4) | Frame Shift Del (DEL) | VAF 31/88 reads (35%) | catalogued as CM151525; called by mutect2, pindel, varscan2
- MYH8 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 42/105 reads (40%) | catalogued as COSV101238705, COSV67960370; called by muse, mutect2, varscan2
- N4BP2 | c.1599C>A p.H533Q | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.433); catalogued as COSV99789224; called by muse, mutect2, varscan2
- NAV3 | c.4973C>A p.P1658H | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.332); catalogued as COSV99894963; called by muse, mutect2, varscan2
- NCOR2 | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772228038, COSV62292874; called by muse, mutect2, varscan2
- NDUFS8 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99693587; called by muse, mutect2, varscan2
- NFXL1 | c.2407A>T p.K803* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV101040110, COSV101040593; called by muse, mutect2, varscan2
- NLRC5 | c.1637G>T p.R546L | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs769612870, COSV99347475, COSV99348137; called by muse, mutect2, varscan2
- NLRP13 | c.2113A>T p.T705S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100738477; called by muse, mutect2, varscan2
- NOBOX | c.523C>A p.R175S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs573084275, COSV56192720, COSV99779661; called by muse, mutect2, varscan2
- NPR3 | c.1060G>T p.V354F | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99423780; called by muse, mutect2, varscan2
- NYAP1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100278665; called by muse, mutect2, varscan2
- OR1L3 | c.644T>C p.I215T | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100506304; called by muse, mutect2, varscan2
- OR2A25 | c.225C>A p.S75R | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV101376415; called by muse, mutect2, varscan2
- OR2M4 | c.220A>T p.I74F | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV60708182; called by muse, mutect2, varscan2
- OR2T6 | c.346G>C p.G116R | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100861630, COSV63215725; called by muse, mutect2, varscan2
- OR4D10 | c.827C>A p.T276N | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as rs1443803454, COSV101597026; called by muse, mutect2, varscan2
- OR51I2 | c.89C>A p.P30H | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100413466; called by muse, mutect2, varscan2
- OR56B1 | c.698C>A p.S233Y | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100402716; called by muse, mutect2, varscan2
- OR5AR1 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100265768, COSV57255089; called by muse, mutect2, varscan2
- OR5B17 | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.175); catalogued as COSV100641916; called by muse, mutect2, varscan2
- OR5D14 | c.691C>A p.R231S | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV100162533; called by muse, mutect2, varscan2
- OR5R1 | c.109G>T p.V37F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100393572; called by muse, mutect2, varscan2
- OR5V1 | c.215G>T p.C72F | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV101011449; called by muse, mutect2, varscan2
- OR7D2 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.137); catalogued as COSV100713072; called by muse, mutect2, varscan2
- OXCT2 | c.942G>C p.M314I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100560375; called by muse, mutect2
- PACS1 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.879); catalogued as COSV100270516; called by muse, mutect2, varscan2
- PANK4 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs140699365, COSV101022551; called by muse, mutect2, varscan2
- PAPPA | c.1637T>A p.L546* | Nonsense Mutation (SNP) | VAF 22/90 reads (24%) | catalogued as COSV100075173; called by muse, mutect2, varscan2
- PARP4 | c.2409T>A p.H803Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101132013; called by muse, varscan2
- PCDH15 | c.1816C>A p.L606I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.759); catalogued as rs748924040, COSV57385420; called by muse, mutect2, varscan2
- PCDH17 | c.173G>C p.R58P | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.142); catalogued as COSV100931974, COSV64979882; called by muse, mutect2, varscan2
- PCDHB8 | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99177314; called by muse, mutect2, varscan2
- PCDHB8 | c.1654G>T p.V552L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.232); catalogued as COSV99177315; called by muse, mutect2, varscan2
- PCDHGA2 | c.1248del p.Y418Tfs*5 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | catalogued as COSV53916514; called by mutect2, pindel, varscan2
- PCDHGB4 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV53892333, COSV99545958; called by muse, mutect2, varscan2
- PCNX4 | c.358A>C p.S120R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV100470768; called by muse, mutect2, varscan2
- PEAR1 | c.2209+1G>T p.X737_splice | Splice Site (SNP) | VAF 38/77 reads (49%) | catalogued as COSV99442253; called by muse, mutect2, varscan2
- PEG3 | c.3471C>A p.Y1157* | Nonsense Mutation (SNP) | VAF 28/141 reads (20%) | catalogued as COSV99690235; called by muse, mutect2, varscan2
- PFKFB1 | c.815G>C p.G272A | Missense Mutation (SNP) | VAF 8/21 reads (38%) | PolyPhen probably damaging (0.988); catalogued as COSV100895835; called by muse, mutect2, varscan2
- PHKA2 | c.3286C>T p.H1096Y | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.358); catalogued as rs148627941, COSV101177413; called by muse, mutect2, varscan2
- PIK3R4 | c.3581C>T p.P1194L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100768275, COSV100768579; called by muse, mutect2, varscan2
- PLCB1 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100571940, COSV62071302; called by muse, mutect2, varscan2
- PLXNA1 | c.485G>A p.S162N | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.287); catalogued as COSV99303988; called by muse, mutect2, varscan2
- PLXNA3 | c.3334C>T p.R1112C | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1376013141, COSV100859947, COSV100860125; called by muse, mutect2, varscan2
- PNMA2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); catalogued as COSV101580646; called by muse, mutect2, varscan2
- POT1 | c.1052T>C p.I351T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100714133; called by muse, mutect2, varscan2
- POU3F1 | c.870G>C p.Q290H | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100884719; called by muse, mutect2, varscan2
- PPM1F | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99601687; called by muse, mutect2, varscan2
- PSG2 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 78/412 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762614620, COSV61545731; called by muse, mutect2, varscan2
- RECK | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100937633; called by muse, mutect2, varscan2
- RHBDL3 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.862); catalogued as rs762346732, COSV99283926; called by muse, mutect2, varscan2
- RIMBP2 | c.992G>T p.S331I | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV55482628, COSV99900343; called by muse, mutect2, varscan2
- ROR1 | c.2419G>T p.G807C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.717); catalogued as COSV100935546; called by muse, mutect2, varscan2
- RTP3 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs922783072, COSV99946989; called by muse, mutect2, varscan2
- RXFP2 | c.94+2T>C p.X32_splice | Splice Site (SNP) | VAF 37/74 reads (50%) | catalogued as COSV100033882; called by muse, mutect2, varscan2
- RYR2 | c.5238C>A p.H1746Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as COSV100772581; called by muse, mutect2, varscan2
- SELP | c.1962C>A p.Y654* | Nonsense Mutation (SNP) | VAF 66/322 reads (20%) | catalogued as COSV99740976; called by muse, mutect2, varscan2
- SELP | c.1534C>A p.P512T | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.71); catalogued as COSV99740981; called by muse, mutect2, varscan2
- SGCD | c.790G>C p.V264L (on ENST00000435422 / NM_001128209.2; = p.V265L on NM_000337.5) | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100550976, COSV61903379; called by muse, mutect2, varscan2
- SIGLEC6 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as COSV100585656; called by muse, mutect2, varscan2
- SLC30A10 | c.1070G>T p.R357M | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.579); catalogued as COSV100751590; called by muse, mutect2, varscan2
- SLC35G2 | c.134A>G p.Y45C | Missense Mutation (SNP) | VAF 46/347 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.338); catalogued as rs200186660, COSV101262092; called by muse, mutect2, varscan2
- SLC4A8 | c.1101+1G>A p.X367_splice | Splice Site (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100177456; called by mutect2, varscan2
- SLCO1B3 | c.47C>G p.S16* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV53936440, COSV99682161; called by muse, mutect2, varscan2
- SMARCAL1 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV100620050, COSV61924357; called by muse, mutect2, varscan2
- SMYD2 | c.248G>A p.W83* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as rs1364152334, COSV100873299; called by muse, mutect2, varscan2
- SOHLH2 | c.772C>G p.P258A | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as COSV101157986; called by muse, mutect2, varscan2
- SORCS1 | c.2918A>T p.Y973F | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.333); catalogued as COSV99549853; called by muse, mutect2, varscan2
- SOX5 | c.1828G>C p.A610P | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100507991; called by muse, mutect2, varscan2
- SPICE1 | c.1778C>G p.S593* | Nonsense Mutation (SNP) | VAF 43/77 reads (56%) | catalogued as COSV55620341, COSV55624955; called by muse, mutect2, varscan2
- SPTA1 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 45/99 reads (45%) | catalogued as COSV100935498; called by muse, mutect2, varscan2
- STAG2 | c.1624G>T p.G542W | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99495164; called by muse, mutect2, varscan2
- STAT4 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100636178; called by muse, mutect2, varscan2
- STK17B | c.318C>G p.I106M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.97); PolyPhen benign (0.052); catalogued as COSV99826289; called by muse, mutect2, varscan2
- SV2C | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769027251, COSV59228129; called by muse, mutect2, varscan2
- TAB2 | c.1823G>A p.C608Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746984589, COSV99645080; called by mutect2, varscan2
- TBC1D32 | c.2570+1G>A p.X857_splice | Splice Site (SNP) | VAF 15/52 reads (29%) | catalogued as COSV99251134; called by muse, mutect2, varscan2
- TEX14 | c.2245G>A p.E749K (on ENST00000240361 / NM_001201457.2; = p.E743K on NM_031272.5) | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1377165011, COSV99542437; called by muse, mutect2, varscan2
- TIMM9 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as COSV99374162; called by muse, varscan2
- TMLHE | c.854C>A p.A285E | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.089); catalogued as COSV100545077; called by muse, varscan2
- TRHDE | c.2849G>A p.R950K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.403); catalogued as COSV99672263; called by mutect2, varscan2
- TRIM5 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs893815108, COSV100000671; called by muse, mutect2, varscan2
- TTN | c.9048G>A p.M3016I (on ENST00000591111; = p.M2970I on NM_003319.4) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | PolyPhen benign (0); catalogued as COSV100627535; called by muse, mutect2, varscan2
- TXLNA | c.1635G>T p.R545S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV101009904; called by muse, mutect2, varscan2
- ULK4 | c.3395C>T p.A1132V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV100095025; called by muse, mutect2, varscan2
- USH2A | c.9725C>G p.A3242G | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV100241735, COSV56322394; called by muse, mutect2, varscan2
- USH2A | c.203A>T p.H68L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs765666540, COSV100241738; called by muse, mutect2, varscan2
- USP46 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV101484307; called by muse, mutect2
- UTP20 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99882449; called by muse, mutect2, varscan2
- VASH2 | c.365+1G>T p.X122_splice | Splice Site (SNP) | VAF 47/140 reads (34%) | catalogued as COSV99663691; called by muse, mutect2, varscan2
- VCAN | c.290A>T p.Y97F | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV99427131; called by muse, mutect2, varscan2
- VPS13B | c.11273T>A p.L3758Q | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100663399; called by muse, mutect2
- VPS8 | c.3625G>A p.G1209R (on ENST00000625842 / NM_001349294.1; = p.G1207R on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.624); catalogued as COSV99803768; called by muse, mutect2
- WDR17 | c.3568C>A p.Q1190K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.966); catalogued as COSV99706740; called by muse, mutect2, varscan2
- XIRP1 | c.1880C>A p.T627N | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100453929, COSV61140392; called by muse, mutect2, varscan2
- ZC2HC1A | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99804416; called by muse, mutect2
- ZFP57 | c.437G>C p.R146T | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV100971954, COSV65306472; called by muse, mutect2, varscan2
- ZIC1 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV99292357; called by muse, mutect2, varscan2
- ZNF254 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100741760; called by muse, mutect2, varscan2
- ZNF257 | c.1582T>A p.S528T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV101448157; called by muse, mutect2, varscan2
- ZNF502 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV99939854; called by muse, mutect2, varscan2
- FZD3 | c.1585del p.E529Nfs*9 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- KLHL1 | c.112del p.L38Cfs*28 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- MRC1 | c.2612A>T p.K871M | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- MYOCD | c.2473_2495del p.L825Afs*4 | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | called by mutect2, pindel
- RILPL1 | c.437_441del p.E146Gfs*6 | Frame Shift Del (DEL) | VAF 12/100 reads (12%) | called by mutect2, pindel
- SLC11A1 | c.1205_1206dup p.L403Sfs*20 | Frame Shift Ins (INS) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- SRCAP | c.7253del p.H2418Lfs*57 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- XYLT2 | c.1967_1968del p.E656Afs*46 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by pindel, varscan2
- ADAM7 | c.2043C>T p.V681= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs149009178; called by muse, mutect2, varscan2
- ANGPT2 | c.678C>T p.I226= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100291166; called by muse, mutect2, varscan2
- C2orf78 | c.2541C>A p.I847= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV101281017, COSV101281028; called by muse, mutect2, varscan2
- CADM2 | c.342C>G p.S114= (on ENST00000407528 / NM_001167674.2; = p.S116= on NM_153184.4) | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV101059194; called by muse, mutect2
- CCDC138 | c.189A>T p.S63= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs186096514, COSV99313134; called by muse, mutect2, varscan2
- CEP250 | c.5841A>T p.A1947= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100699155; called by muse, mutect2, varscan2
- CPAMD8 | c.594C>T p.T198= (on ENST00000651564; = p.T151= on NM_015692.5) | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as rs770682589, COSV99359761; called by muse, mutect2, varscan2
- CSPP1 | c.1884G>A p.P628= (on ENST00000676605; = p.P587= on NM_024790.6) | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs201940935, COSV51582651; called by muse, mutect2, varscan2
- CTNNA3 | c.2305C>T p.L769= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV101041591, COSV99057493; called by muse, mutect2, varscan2
- DACH2 | c.1041C>A p.A347= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV100913815; called by muse, mutect2, varscan2
- DIPK2A | c.570C>T p.G190= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs369044041; called by muse, varscan2
- DLGAP2 | c.453G>T p.V151= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs769632607, COSV101422622; called by muse, mutect2, varscan2
- DPP10 | c.843G>T p.P281= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs146251151, COSV100071178; called by muse, mutect2, varscan2
- EGFLAM | c.1926G>T p.R642= | Silent (SNP) | VAF 30/203 reads (15%) | catalogued as COSV100380717; called by muse, varscan2
- EGFLAM | c.2034C>T p.G678= | Silent (SNP) | VAF 28/280 reads (10%) | catalogued as COSV59300629; called by muse, varscan2
- ELAPOR2 | c.762A>C p.T254= (on ENST00000450689 / NM_001142749.3; = p.T87= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV99789312; called by muse, mutect2, varscan2
- F3 | c.729C>A p.G243= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV61845033; called by muse, varscan2
- FAM160B2 | c.1200G>C p.L400= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99249210; called by muse, mutect2, varscan2
- FKRP | c.1137G>C p.R379= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100586723; called by muse, mutect2, varscan2
- FLT4 | c.3178C>A p.R1060= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV56105548, COSV99988729; called by muse, mutect2, varscan2
- FOXG1 | c.684C>A p.S228= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV100487043; called by muse, varscan2
- FOXL2NB | c.300C>A p.R100= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV100374789; called by muse, mutect2, varscan2
- GRAMD1B | c.1410C>T p.H470= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs752871193, COSV100455173; called by muse, mutect2, varscan2
- HHIPL2 | c.201C>T p.F67= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs777269842, COSV58563882; called by muse, mutect2, varscan2
- HTR5A | c.852C>G p.A284= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV99839950; called by muse, mutect2, varscan2
- IGKV1D-13 | c.150C>A p.G50= | Silent (SNP) | VAF 34/171 reads (20%) | catalogued as rs368959403; called by muse, mutect2, varscan2
- IVL | c.300A>G p.K100= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100908261; called by muse, mutect2, varscan2
- KCNJ3 | c.432C>A p.I144= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs762930583, COSV99716388; called by muse, mutect2, varscan2
- KCNQ3 | c.1995G>T p.S665= | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as rs759776061, COSV101195748, COSV101196387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA0100 | c.6411C>T p.D2137= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs768098939, COSV99972288; called by muse, mutect2, varscan2
- LGALS3BP | c.1662G>A p.K554= | Silent (SNP) | VAF 12/168 reads (7%) | catalogued as COSV99431897; called by muse, mutect2
- LRIT1 | c.1515C>A p.P505= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100928145; called by muse, mutect2, varscan2
- LRRC52 | c.858C>T p.D286= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs770691375, COSV54232381, COSV54233345; called by mutect2, varscan2
- MAGEB1 | c.987C>A p.A329= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV100975087; called by muse, mutect2, varscan2
- MAPK9 | c.1044A>G p.A348= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100558598; called by muse, mutect2, varscan2
- MBOAT1 | c.1425A>G p.P475= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100209162; called by muse, mutect2, varscan2
- MYLK3 | c.897G>A p.E299= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as COSV101189197; called by muse, mutect2, varscan2
- NLRP3 | c.2631C>A p.A877= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs1401066630, COSV100276552; called by muse, mutect2, varscan2
- OR4A5 | c.894C>G p.L298= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs772352354, COSV100157277, COSV60524565; called by muse, mutect2
- OR51G1 | c.349C>T p.L117= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100429398; called by muse, mutect2, varscan2
- OR52N1 | c.486T>G p.T162= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV57694199; called by muse, mutect2, varscan2
- OR5AC2 | c.786G>T p.V262= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100684484; called by muse, mutect2, varscan2
- OR5L1 | c.711C>T p.A237= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as rs1249263359, COSV100450061; called by muse, mutect2, varscan2
- OR8B3 | c.822T>A p.S274= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as rs762486067, COSV100660432; called by muse, mutect2, varscan2
- PCDHB6 | c.1083C>A p.I361= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs1554277666, COSV99170956; called by muse, mutect2, varscan2
- PIGL | c.378C>T p.H126= | Silent (SNP) | VAF 21/132 reads (16%) | catalogued as COSV99848822; called by muse, mutect2, varscan2
- PLEK | c.480C>T p.C160= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs151222226; called by muse, mutect2, varscan2
- PRR22 | c.444G>T p.P148= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV100288438, COSV57832089; called by muse, mutect2, varscan2
- RTKN2 | c.1515C>T p.P505= | Silent (SNP) | VAF 28/158 reads (18%) | catalogued as COSV100189600; called by muse, mutect2, varscan2
- SLC17A6 | c.1161C>A p.I387= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as COSV99582264; called by muse, mutect2, varscan2
- SLC9A2 | c.2277G>C p.T759= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as rs747391806, COSV99296724; called by muse, mutect2, varscan2
- SLITRK6 | c.1218G>A p.S406= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs920496139, COSV68390008; called by muse, mutect2, varscan2
- STAC | c.924A>T p.P308= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99830691; called by muse, mutect2, varscan2
- TAF9B | c.297A>G p.K99= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV100540756; called by muse, mutect2, varscan2
- TRPM3 | c.4104A>T p.L1368= (on ENST00000357533 / NM_001366142.2; = p.L1223= on NM_020952.6) | Silent (SNP) | VAF 36/163 reads (22%) | catalogued as COSV100678593; called by muse, mutect2, varscan2
- URB2 | c.2682C>T p.I894= | Silent (SNP) | VAF 57/147 reads (39%) | catalogued as rs749447215, COSV99271824; called by muse, mutect2, varscan2
- VEGFA | c.603G>A p.T201= (on ENST00000523873 / NM_001171623.1; = p.T364= on NM_003376.6) | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs745609508, COSV57877937; called by mutect2, varscan2
- ZSWIM8 | c.4899C>G p.T1633= (on ENST00000605216 / NM_001242487.2; = p.T1638= on NM_015037.3) | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV100014338; called by muse, mutect2, varscan2
- DENND10P1 | n.989T>G | RNA (SNP) | VAF 35/178 reads (20%) | called by muse, mutect2, varscan2
- FAIM | c.-22-1673C>T | Intron (SNP) | VAF 47/124 reads (38%) | catalogued as COSV100624011; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85716A>T | Intron (SNP) | VAF 34/130 reads (26%) | catalogued as COSV72277674; called by muse, mutect2, varscan2
- OR56A1 | c.-10G>T | 5'UTR (SNP) | VAF 33/131 reads (25%) | catalogued as rs868144966, COSV100360535; called by muse, mutect2, varscan2
- RPGR | c.2520+1209A>G | Intron (SNP) | VAF 3/16 reads (19%) | catalogued as rs764724151, CD035011; called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-23932G>T | Intron (SNP) | VAF 23/174 reads (13%) | catalogued as rs777620829, COSV101044999; called by muse, mutect2, varscan2
- SNRPN | chr15:24982015 T>A | 3'Flank (SNP) | VAF 116/281 reads (41%) | called by muse, mutect2, varscan2
- TTN | c.10360+4606C>A | Intron (SNP) | VAF 22/99 reads (22%) | catalogued as rs866383926, COSV100627534; called by muse, mutect2, varscan2
- WNK1 | c.2140-3284C>T | Intron (SNP) | VAF 46/136 reads (34%) | catalogued as rs775154028, COSV100267909, COSV60027358; ClinVar: uncertain significance; called by muse, mutect2, varscan2
